Somatic mutation profile of tumor specimen TCGA-93-7347-01A (aliquot TCGA-93-7347-01A-11D-2184-08) from TCGA case TCGA-93-7347, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.5 years (27,949 days).
Specimen TCGA-93-7347-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddcc2fd9-c351-4632-921e-5a9d0464c2a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-7347-10A (Blood Derived Normal), aliquot TCGA-93-7347-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ba7dbf0-2634-4340-8d26-f182c3665a7d

The open-access MAF lists 126 somatic variants for this specimen: 95 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 28, Nonsense Mutation 6, Frame Shift Ins 2, Frame Shift Del 2, Splice Region 1, Intron 1, Splice Site 1, 3'UTR 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.3065C>A p.A1022D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs1393206482, COSV100568016; called by muse, mutect2
- ADGRL3 | c.2254C>G p.L752V (on ENST00000506720 / NM_001322402.2; = p.L684V on NM_015236.6) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.927); catalogued as COSV72230815; called by muse, mutect2
- ADSS2 | c.1052T>C p.M351T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as rs1437931736, COSV63695321; called by muse, mutect2, varscan2
- AFP | c.298C>A p.H100N | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV99890184; called by muse, mutect2
- ANKMY1 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as COSV99802692; called by muse, mutect2
- ANKRD13B | c.1099A>G p.K367E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV61471132; called by muse, mutect2, varscan2
- ANKS1B | c.1232G>T p.C411F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV61355134; called by muse, mutect2, varscan2
- AP1B1 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs773851419, COSV58018532; called by muse, mutect2, varscan2
- C19orf44 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as COSV55612552; called by muse, mutect2, varscan2
- CACNG8 | c.435C>A p.C145* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV54415082; called by muse, mutect2, varscan2
- CDH23 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54937538; called by muse, mutect2, varscan2
- CDH8 | c.1762A>T p.S588C | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54872083; called by muse, mutect2, varscan2
- CELF3 | c.409T>A p.C137S | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51884053; called by muse, mutect2, varscan2
- CHD8 | c.3196G>T p.E1066* (on ENST00000646647 / NM_001170629.2; = p.E787* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as rs1555315246, COSV67870865; called by muse, mutect2, varscan2
- CRYBG1 | c.2603C>T p.S868L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.041); catalogued as COSV64812552; called by muse, mutect2
- CUL4A | c.1583_1586del p.L528Qfs*15 (on ENST00000375440 / NM_001008895.4; = p.L428Qfs*15 on NM_003589.3) | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | catalogued as rs1035929081; called by mutect2, pindel
- DCAF8L1 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV71595311, COSV71595342, COSV71595398; called by muse, mutect2, varscan2
- DCPS | c.179A>T p.K60I | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55011255; called by muse, mutect2, varscan2
- DES | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as CM051448, COSV100900475, COSV64660407; called by muse, mutect2
- EIF3C | c.919G>T p.G307* | Nonsense Mutation (SNP) | VAF 65/969 reads (7%) | catalogued as COSV59059672; called by muse, mutect2
- EPG5 | c.7420C>T p.R2474W | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1188184108, COSV56350945; called by muse, mutect2, varscan2
- FAM47A | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.736); catalogued as COSV60497437; called by muse, mutect2, varscan2
- FAM71B | c.1592C>A p.A531D | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV57229448; called by muse, mutect2, varscan2
- FLI1 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55645173; called by muse, mutect2, varscan2
- FRMPD4 | c.1774C>A p.H592N | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.491); catalogued as COSV101043508; called by muse, mutect2
- GOLGB1 | c.9625A>C p.T3209P | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV58857002; called by muse, mutect2, varscan2
- GPA33 | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63301282; called by muse, mutect2, varscan2
- GPKOW | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV50243030; called by muse, mutect2, varscan2
- GPR27 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55204949; called by muse, mutect2
- GUCY1A2 | c.331A>T p.R111W | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV56489133; called by muse, mutect2, varscan2
- HIPK2 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61228379; called by muse, mutect2, varscan2
- HTR3B | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as COSV52745197; called by muse, mutect2, varscan2
- IL12A | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as rs774591542, COSV59759484; called by muse, mutect2
- IL16 | c.3318G>T p.K1106N (on ENST00000302987 / NM_172217.5; = p.K405N on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57264364; called by muse, mutect2, varscan2
- ITPR1 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56985186; called by muse, mutect2
- KIAA1210 | c.1067A>C p.Q356P | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV68176828, COSV68177552; called by muse, mutect2, varscan2
- LRP1 | c.7775G>T p.G2592V | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54514130; called by muse, mutect2, varscan2
- LRP1B | c.7259G>A p.W2420* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV67230229; called by muse, mutect2, varscan2
- LRRIQ1 | c.5050G>C p.D1684H | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67832054; called by muse, mutect2, varscan2
- MDH1B | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV65590150; called by muse, mutect2, varscan2
- MPRIP | c.1468G>T p.V490L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV57927688; called by muse, mutect2, varscan2
- MUC16 | c.4745C>A p.S1582Y | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs928905098, COSV67471920, COSV67493425; called by muse, mutect2, varscan2
- MUS81 | c.998A>T p.E333V | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV57260395; called by muse, mutect2, varscan2
- MYO15A | c.1431C>A p.F477L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV52758333; called by muse, mutect2, varscan2
- NAA60 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV62654992; called by muse, mutect2
- NALCN | c.4819C>T p.R1607W | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs866709006, COSV51915914; called by muse, mutect2
- NEDD4L | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV56846261; called by muse, mutect2
- OR51V1 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV58315387; called by muse, mutect2, varscan2
- OR8H3 | c.712T>A p.F238I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV57909412; called by muse, mutect2, varscan2
- OR8J3 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV56879444, COSV56881739; called by muse, mutect2, varscan2
- ORAI3 | c.473G>C p.G158A | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52688438; called by muse, mutect2, varscan2
- PACSIN1 | c.1053C>G p.D351E | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV55060430; called by muse, mutect2
- PBX4 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV52061943; called by muse, mutect2, varscan2
- PIK3R6 | c.1199C>A p.P400H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100266702; called by muse, mutect2
- PLB1 | c.3199T>G p.W1067G | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV59827477; called by muse, mutect2, varscan2
- PLEC | c.10810G>T p.A3604S (on ENST00000322810 / NM_201380.4; = p.A3494S on NM_000445.5) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59646048; called by muse, mutect2, varscan2
- PLK2 | c.1756-2A>G p.X586_splice | Splice Site (SNP) | VAF 18/126 reads (14%) | catalogued as COSV57107857; called by muse, mutect2, varscan2
- PSENEN | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV53075341, COSV99495131; called by muse, mutect2, varscan2
- PSMA1 | c.781A>G p.M261V | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV67165996; called by muse, mutect2, varscan2
- PTPRM | c.3920A>T p.H1307L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV59863247; called by muse, mutect2, varscan2
- RELN | c.5472G>C p.E1824D | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.958); catalogued as COSV59007528; called by muse, mutect2, varscan2
- RESF1 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 7/82 reads (9%) | catalogued as COSV57022823; called by muse, mutect2
- RPL36A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV58120565; called by muse, mutect2
- RYR1 | c.11866G>T p.V3956L | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62099680; called by muse, mutect2, varscan2
- RYR2 | c.7550A>T p.N2517I | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63689852; called by muse, mutect2, varscan2
- SCN7A | c.4903G>T p.A1635S | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV69272251; called by muse, mutect2, varscan2
- SETD3 | c.1031G>T p.S344I | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59284771; called by muse, mutect2, varscan2
- SETX | c.808A>T p.I270L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV56387217; called by muse, mutect2, varscan2
- SH3YL1 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764782475, COSV62156620; called by muse, mutect2, varscan2
- SHCBP1 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 33/261 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57647978; called by muse, mutect2, varscan2
- SIX6 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as rs1411196233, COSV59801836, COSV59802580; called by muse, mutect2, varscan2
- SLC13A2 | c.1441A>G p.T481A | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV58995653; called by muse, mutect2, varscan2
- SLC25A38 | c.279C>T p.S93= | Splice Region (SNP) | VAF 92/754 reads (12%) | catalogued as COSV56193656, COSV56194641; called by muse, mutect2, varscan2
- SLC6A8 | c.1674G>T p.E558D | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.056); catalogued as COSV53472385; called by muse, mutect2, varscan2
- SLC9A3 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV53801878; called by muse, mutect2, varscan2
- SP4 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV56023241; called by muse, mutect2
- SPTBN2 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746994330, COSV100019564; called by muse, mutect2
- SSR4 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51245865, COSV51247402; called by muse, mutect2, varscan2
- STK11IP | c.1651G>C p.G551R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV55250731; called by muse, mutect2
- SUPT16H | c.908A>C p.N303T | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs754001146, COSV53525541, COSV99359694; called by muse, mutect2, varscan2
- TAF6L | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.156); catalogued as COSV53669166; called by muse, mutect2, varscan2
- TBC1D8 | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65213231; called by muse, mutect2, varscan2
- TNR | c.2161A>C p.T721P | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV54890042; called by muse, mutect2
- TRIM21 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV54344610; called by muse, mutect2, varscan2
- TRPM1 | c.4532T>A p.V1511D | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.042); catalogued as rs556799723, COSV56635998; called by muse, mutect2
- TSHZ1 | c.214G>T p.A72S (on ENST00000580243 / NM_001308210.2; = p.A27S on NM_005786.6) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV100433832; called by mutect2, varscan2
- ZNF250 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.191); catalogued as COSV52969469; called by muse, mutect2, varscan2
- ZNF534 | c.535G>T p.D179Y (on ENST00000332323 / NM_001143939.3; = p.D166Y on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1455623228, COSV56515534, COSV56521526; called by muse, mutect2, varscan2
- ZNF668 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.233); catalogued as COSV56215218; called by muse, mutect2
- ZNF783 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV65185637; called by muse, mutect2, varscan2
- ZNF98 | c.202G>T p.G68* | Nonsense Mutation (SNP) | VAF 18/141 reads (13%) | catalogued as COSV63337142; called by muse, mutect2, varscan2
- C6 | c.159dup p.K54* | Frame Shift Ins (INS) | VAF 31/124 reads (25%) | called by mutect2, pindel, varscan2
- DHX32 | c.560_564del p.I187Rfs*7 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, varscan2
- MTAP | c.174dup p.A59Cfs*53 | Frame Shift Ins (INS) | VAF 47/257 reads (18%) | called by mutect2, pindel, varscan2
- ANKMY1 | c.864G>T p.V288= | Silent (SNP) | VAF 10/137 reads (7%) | catalogued as COSV99802698; called by muse, mutect2
- ASTN2 | c.2379C>A p.V793= (on ENST00000313400 / NM_001365069.1; = p.V742= on NM_014010.5) | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as COSV57784787; called by muse, mutect2, varscan2
- ATOH8 | c.42C>T p.T14= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100092366, COSV60400536; called by muse, mutect2, varscan2
- BARX2 | c.105C>A p.T35= | Silent (SNP) | VAF 35/234 reads (15%) | catalogued as COSV55650757; called by muse, mutect2, varscan2
- CDC25C | c.942G>T p.L314= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV60399744; called by muse, mutect2
- CELSR1 | c.6837C>T p.S2279= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV53091939; called by muse, mutect2
- CRPPA | c.696T>C p.Y232= (on ENST00000407010 / NM_001368197.1; = p.Y182= on NM_001101417.4) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV67906545; called by muse, mutect2
- CYP4F3 | c.1152C>T p.C384= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as COSV55409919, COSV55410605; called by muse, mutect2, varscan2
- FAM47B | c.864C>G p.P288= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs142684131, COSV61454425; called by muse, mutect2, varscan2
- FAT4 | c.10797A>T p.T3599= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as COSV58689614; called by muse, mutect2, varscan2
- HEATR1 | c.3822C>A p.P1274= | Silent (SNP) | VAF 6/109 reads (6%) | catalogued as COSV100857716; called by muse, mutect2
- HS3ST2 | c.859C>A p.R287= | Silent (SNP) | VAF 32/296 reads (11%) | catalogued as COSV54463215, COSV54466823; called by muse, mutect2, varscan2
- IGLV3-16 | c.319C>T p.L107= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- KCNB2 | c.636C>A p.L212= | Silent (SNP) | VAF 71/276 reads (26%) | catalogued as COSV73050676; called by muse, mutect2, varscan2
- LILRB5 | c.204C>A p.A68= | Silent (SNP) | VAF 38/251 reads (15%) | catalogued as COSV60258114; called by muse, mutect2, varscan2
- LRRC24 | c.597G>A p.L199= | Silent (SNP) | VAF 86/316 reads (27%) | catalogued as COSV52879992; called by muse, mutect2, varscan2
- MUC5B | c.5367G>A p.E1789= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV71592674; called by muse, mutect2, varscan2
- OR4C15 | c.39A>T p.A13= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as rs756200625, COSV58953264; called by muse, mutect2, varscan2
- OR6Q1 | c.636G>A p.L212= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV56933367; called by muse, mutect2, varscan2
- OTOL1 | c.1362C>A p.V454= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100020117; called by muse, mutect2
- PTPRK | c.285G>T p.L95= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV63899681; called by muse, mutect2
- RCC1 | c.1047G>T p.S349= | Silent (SNP) | VAF 51/330 reads (15%) | catalogued as COSV65779575; called by muse, mutect2, varscan2
- SERPINB6 | c.1119C>T p.P373= (on ENST00000612421 / NM_001271823.2; = p.P354= on NM_004568.6) | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV59566084; called by muse, mutect2
- SFSWAP | c.2610A>G p.S870= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV55522326; called by muse, mutect2, varscan2
- STK10 | c.1182A>C p.P394= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs778648205, COSV51574834; called by muse, mutect2
- TMEM196 | c.333G>T p.A111= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- TTC3 | c.36G>T p.A12= | Silent (SNP) | VAF 42/309 reads (14%) | catalogued as COSV61291301; called by muse, mutect2, varscan2
- URGCP | c.1764G>T p.T588= (on ENST00000453200 / NM_001077663.3; = p.T579= on NM_017920.4) | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV56248471; called by muse, mutect2, varscan2
- CDH11 | c.*1C>T | 3'UTR (SNP) | VAF 15/112 reads (13%) | catalogued as rs781108761, COSV99219178; called by muse, mutect2, varscan2
- TRAK1 | c.287-16428G>A | Intron (SNP) | VAF 12/215 reads (6%) | catalogued as COSV100410176; called by muse, mutect2
- XIST | n.9583G>T | RNA (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
